Somatic mutation profile of tumor specimen MP2PRT-PAUCBI-TMP1-A (aliquot MP2PRT-PAUCBI-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUCBI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,489 days).
Specimen MP2PRT-PAUCBI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b101d8bb-b170-4447-87b2-f35df2c72260.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCBI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCBI-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24a82bde-774a-4e6a-9207-de8a4c46f2b5

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF17 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 18/583 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1166686049; called by muse, mutect2
- CDX4 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as rs1268309313; called by muse, mutect2
- DSG3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 57/466 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs142415015; called by muse, mutect2, varscan2
- NPNT | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 21/360 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs780911808, COSV59752349; called by muse, mutect2
- NYAP2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 28/494 reads (6%) | catalogued as COSV56013284, COSV56015077; called by muse, mutect2
- PIWIL1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.32); catalogued as rs755399300, COSV55348877; called by muse, mutect2
- SSX3 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 75/93 reads (81%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs782421029, COSV100035387; called by muse, mutect2, varscan2
- FSIP2 | c.2676A>G p.I892M | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCNJ5 | c.795C>T p.D265= | Silent (SNP) | VAF 35/514 reads (7%) | catalogued as rs757895735, COSV57971194; ClinVar: likely benign; called by muse, mutect2
